Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YE, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YE-01A (Primary Tumor).

Patient: [REDACTED]

Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Brain tumor left frontal anaplastic astrocytoma.

GROSS EXAMINATION:

A. "Brain tumor (AF1-2)", received fresh. A 6.5 x 5.0 x 3.0 cm resection of brain tissue is received. Representative tissue is frozen as AF1-2, the frozen section remnants are submitted in respective blocks A1-2. Additional representative sections are submitted as A3-8.

INTRA OPERATIVE CONSULTATION:

A. "Brain tumor": AF1- gliosis, atypical cells
AF2- glioblastoma

MICROSCOPIC EXAMINATION:

Permanent sections reveal a highly cellular pleomorphic population of astrocytes consistent with a high grade glioma. The area interpreted as necrosis on frozen section as AF2 actually represents an area of hemorrhage as seen in permanent sections.

DIAGNOSIS:

A. "BRAIN TUMOR":

ANAPLASTIC ASTROCYTOMA (WHO GRADE III). SEE COMMENT.

COMMENT: Hemorrhage due to surgical trauma, present in permanent section on block A2 was interpreted as frank necrosis at frozen section. No frank necrosis is appreciable in any of the permanent sections, making this an anaplastic astrocytoma.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ICD-O-3
Astrocytoma, grade III 9401/3
Site ^{chief} Brain supratentorial NOS C71.0
^{path} @ Brain, frontal lobe C71.1
JS 6/5/14

Printed by:

Source: NCI Genomic Data Commons file dc9f16d1-a384-4e33-a9c1-f49f50314913 (TCGA-E1-A7YE.695BEEA8-B980-4B04-BB43-13B097B00F46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).